CGCI case BLGSP-71-27-00509 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/495aa73b-6cda-4f73-8c43-d6d035832a54

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 34 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 34.9 years (12,736 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,973 days (5.4 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Mesenteric lymph nodes; Sites of involvement: Bone marrow / Soft tissue / Kidney, NOS / Ovary, NOS / Uterus.
   Pathology details: Lymph node involved site: Mediastinal.
   Pathology details: Lymph node involved site: Mesenteric.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Axillary; Lymph nodes positive: 2; Lymph nodes tested: 2; Tumor largest dimension diameter: 10 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX-M; Days to treatment start: 0 days; Days to treatment end: 117 days; Number of cycles: 3; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: IVAC; Days to treatment start: 0 days; Days to treatment end: 117 days; Number of cycles: 3; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Methotrexate + Not Otherwise Specified + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days; Days to treatment end: 117 days; Number of cycles: 3; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 2.
- Days to follow up: 1,973 days (5.4 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -131.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD19 (IHC): Positive.
- CD20 (IHC): Positive.
- CD22 (IHC): Positive.
- CD3 (IHC): Negative.
- CD45 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC other (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- PAX5 (IHC): Positive.
- Test (IHC): Negative; Specialized molecular test: TdT.
- Lactate Dehydrogenase 2780 [Blood test normal range upper: 250].

Other clinical attributes
- Day -131: Comorbidities: HIV/AIDS.
- Day -131: Risk factors: HIV/AIDS.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.
- Day 0: Weight: 83.7 kg; Height: 161 cm; BMI: 32.3; CD4 count: 113; Haart treatment indicator: Yes; HIV viral load: 565000.
- Day 1,973: Nadir CD4 count: 273.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-27-00509-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-27-00509-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-27-00509-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-27-00509-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-27-00509-01-Ki67: Tissue microarray coordinates: C1,E3,C5.
  Slide BLGSP-71-27-00509-01-CD3: Tissue microarray coordinates: C1,E3,C5.
  Slide BLGSP-71-27-00509-01-HE-1: Tissue microarray coordinates: C1,E3,C5.
  Slide BLGSP-71-27-00509-01-CD10: Tissue microarray coordinates: C1,E3,C5.
  Slide BLGSP-71-27-00509-01-BCL6: Tissue microarray coordinates: C1,E3,C5.
  Slide BLGSP-71-27-00509-01-CD20: Tissue microarray coordinates: C1,E3,C5.
  Slide BLGSP-71-27-00509-01-BCL2: Tissue microarray coordinates: C1,E3,C5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 5; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: excision, omentectomy, hysterectomy, oopherectomy, lymph node dissection (all at the same time); Lymph nodes examined: Yes; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone Marrow; Extranodal involvement site: Soft Tissue (muscle, ligaments, subcutaneous); Extranodal involvement site: Kidney; Extranodal involvement site: Ovary; Extranodal involvement site: Uterus.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 2780; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD45.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD10 (weak positivity).
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD22.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: PAX5.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: TdT.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: cyclophosphamide + Solumedrol, doxorubicin + vincristine, R-CODOX-M/IVAC x3; Pharma adjuvant cycles count: 3.
